TARGET case TARGET-40-NAAFJL — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/04b85690-af35-5539-9389-436e4a17163e

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 16 years; Vital status: Dead; Days to death: 246 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 16.6 years (6,045 days); Year of diagnosis: 2005; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 246 days; Sites of involvement: Lung, NOS.
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Cisplatin.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Methotrexate.

Follow-up (2 entries)
- Days to follow up: 0 days; Days to first event: 0 days; First event: Presented with Metastases.
- Days to follow up: 246 days; Year of follow up: 2005.

Biospecimens (1 sample)
- Sample TARGET-40-NAAFJL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAFJL-01A-01:
- Specimen Type: frozen solid tumor
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 99
- % Non Tumor Nuclei: Top from Biopsy: 1
- % Cellular Tumor: Top from Biopsy: 94
- % Normal: Top from Biopsy: 5
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 1
- % Tumor Nuclei: Bottom from Biopsy: 90
- % Non Tumor Nuclei: Bottom from Biopsy: 10
- % Cellular Tumor: Bottom from Biopsy: 45
- % Normal: Bottom from Biopsy: 5
- % Stroma: Bottom from Biopsy: 0
- % Necrosis: Bottom from Biopsy: 50
- PASS/FAIL: pass

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- First Event: Presented With Mets
- Event Free Survival Time in Days: 0
- Overall Survival Time in Days: 246
- Disease at diagnosis: Metastatic
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Tibia
- Specific tumor region: Proximal
- Definitive Surgery: NA - no surgery
- Primary site progression: No
- Therapy: MTX, Adria, Cis
